Gene-level copy-number profile of tumor specimen TCGA-CR-7383-01A from TCGA case TCGA-CR-7383, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 79.7 years (29,122 days).
Specimen TCGA-CR-7383-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.27ade9a6-30aa-496a-9e21-44fef71bd2b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7383-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ce30b3c4-6e2b-44e6-a2fb-a4295f756e08

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 291; copy number 1: 1,202; copy number 2: 16,768; copy number 3: 27,226; copy number 4: 9,146; copy number 5: 4,308; copy number 6: 379; copy number 7: 21; copy number 8: 66; copy number 9: 32; copy number 11: 20; copy number 15: 101; copy number 20: 101; copy number 23: 36; copy number 24: 113.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7383-01A-11D-2128-01): tumor purity 0.33, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 291 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,507,452–25,089,151, 92 genes (within-gene range 0–2) (broad region; genes not listed).
- chr9:26,746,953–29,318,952, 34 genes: AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1.
- chr9:30,935,485–32,293,692, 9 genes: FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281.
- chr9:35,906,202–36,171,334, 14 genes: HRCT1, SPAAR, AL135841.1, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN.
- chr9:37,915,898–43,045,120, 142 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 490 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:63,957,874–63,981,043, 2 genes, copy number 7 (within-gene range 4–7): HTR1A, AC122707.1.
- chr8:84,828,573–85,617,512, 19 genes, copy number 7: AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1.
- chr11:44,564,427–48,611,000, 132 genes, copy number 8–15 (broad region; genes not listed).
- chr11:69,000,765–71,928,654, 91 genes, copy number 9–23 (broad region; genes not listed).
- chr11:71,938,671–71,939,544, 1 gene, copy number 23: AP002490.2.
- chr12:61,231,159–73,208,317, 234 genes, copy number 11–24 (broad region; genes not listed).
- chr13:63,667,681–64,076,044, 11 genes, copy number 9: LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1.

Autosomal genes at a single copy (total copy number 1): 376. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
